TCGA case TCGA-55-7573 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e41153b-9faf-45c3-8397-8a428ef5c0d5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.0 years (26,302 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 4 days; Disease response: Tumor Free.
- Days to follow up: 487 days (1.3 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 51; FEV1/FVC after bronchodilator (%): 119; FEV1/FVC before bronchodilator (%): 115; FEV1 after bronchodilator (% of reference): 134; FEV1 before bronchodilator (% of reference): 130.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1983.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-55-7573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-55-7573-01A-01-TS1: Section location: Top; Percent tumor nuclei: 65; Percent necrosis: 0.
  Slide TCGA-55-7573-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-55-7573-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-55-7573-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Renal cell carcinoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy L KIRC. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 487 days; disease-specific survival: no event (censored), 487 days; disease-free interval: no event (censored), 487 days; progression-free interval: no event (censored), 487 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-55-7573-01A-11D-2035-01): tumor purity 0.33, ploidy 3.2, whole-genome doublings 1.
